Gene-level copy-number profile of tumor specimen TARGET-40-PAVCLP-01A from TARGET case TARGET-40-PAVCLP, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.1 years (4,062 days).
Specimen TARGET-40-PAVCLP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.a8440095-6fa0-5560-9f53-6b11eaf650fd.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAVCLP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate.
https://portal.gdc.cancer.gov/files/677b8501-d917-4134-8c6c-0bdd3dbc9cb1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 560; copy number 1: 20,189; copy number 2: 36,197; copy number 3: 2,605; copy number 4: 238; copy number 5: 383; copy number 7: 37; copy number 8: 2; copy number 9: 25; copy number 10: 30.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,832,189, 2 genes: CFHR3, CFHR1.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr5:79,000,112–79,001,124, 1 gene: AC020937.1.
- chr10:87,591,607–89,017,059, 35 genes: AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 477 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–55,837,489, 89 genes, copy number 7–10 (broad region; genes not listed).
- chr5:191,495–693,352, 24 genes, copy number 5 (within-gene range 4–5): LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:16,853,994–24,738,195, 104 genes, copy number 5 (broad region; genes not listed).
- chr5:38,845,858–40,798,374, 24 genes, copy number 5 (within-gene range 2–5): OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1.
- chr6:63,193,072–65,707,226, 24 genes, copy number 5–7 (within-gene range 3–7): AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr7:157,087,955–157,111,072, 2 genes, copy number 8: AC006967.1, AC006967.3.
- chr7:157,335,381–157,518,658, 4 genes, copy number 5 (within-gene range 1–5): DNAJB6, AC006372.3, AC006372.1, AC006372.2.
- chr8:38,176,533–38,560,939, 16 genes, copy number 5: BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1.
- chr14:105,664,633–106,875,071, 190 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,638. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
